Gene-level copy-number profile of specimen HCM-CSHL-0658-C20-85O from HCMI case HCM-CSHL-0658-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.9 years (21,879 days).
Specimen HCM-CSHL-0658-C20-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 731e34bf-8817-4ed7-8074-a1049b4b14d3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0658-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/4b439393-fffe-4dc8-80f5-41b355a6e4df

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,013; copy number 2: 11,735; copy number 3: 23,043; copy number 4: 19,945; copy number 5: 1,593; copy number 6: 1,415; copy number 7: 149; copy number 9: 2; copy number 19: 19.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,412,827–12,414,373, 1 gene: AC087203.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 170 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,648,075–2,838,823, 2 genes, copy number 9: AC246817.2, AC246817.1.
- chr8:32,911,493–32,911,598, 1 gene, copy number 19: RNU6-663P.
- chr8:38,269,704–38,382,272, 1 gene, copy number 19 (within-gene range 1–19): NSD3.
- chr8:38,335,981–38,704,855, 11 genes, copy number 19: AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr8:49,909,789–51,015,165, 6 genes, copy number 7: SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1.
- chr8:142,784,882–145,066,685, 143 genes, copy number 7 (broad region; genes not listed).
- chr17:22,090,743–22,299,893, 6 genes, copy number 19: UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5.

Autosomal genes at a single copy (total copy number 1): 1,012. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
